Gene-level copy-number profile of tumor specimen MP2PRT-PARVFZ-TMP1-A from MP2PRT case MP2PRT-PARVFZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,630 days).
Specimen MP2PRT-PARVFZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 141a0cc0-409c-4d5f-b81d-b59bf55b95c5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARVFZ-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,244 have no estimate.
https://portal.gdc.cancer.gov/files/b84e1c10-f859-44b5-bb1c-11ed83a81aa4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 187; copy number 1: 130; copy number 2: 54,812; copy number 3: 3,217; copy number 4: 33.

Homozygous deletions (total copy number 0; autosomes only): 187 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,040,224–89,046,466, 2 genes (within-gene range 0–1): IGKV1-12, IGKV1-13.
- chr2:89,170,775–89,213,928, 7 genes (within-gene range 0–1): IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27.
- chr2:89,252,211–89,310,144, 8 genes: IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38.
- chr2:90,159,840–90,160,335, 1 gene (within-gene range 0–1): IGKV1D-12.
- chr2:90,179,889–90,235,370, 5 genes: IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7.
- chr7:38,257,879–38,265,678, 1 gene (within-gene range 0–1): TRGC1.
- chr7:38,276,259–38,311,808, 5 genes (within-gene range 0–1): TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr14:22,438,547–22,439,015, 2 genes (within-gene range 0–4): TRDD1, TRDD2.
- chr14:105,672,308–106,631,653, 141 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,637,718–106,639,657, 2 genes (within-gene range 0–1): IGHVII-60-1, IGHV4-61.
- chr14:106,657,725–106,672,073, 3 genes (within-gene range 0–1): IGHV3-64, IGHV3-65, IGHVII-65-1.
- chr22:22,834,865–22,893,818, 10 genes (within-gene range 0–1): AC245028.2, IGLV3-7, IGLV3-6, IGLV2-5, IGLV3-4, IGLV4-3, IGLV3-2, IGLV3-1, MIR5571, IGLJ1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 130. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
